Somatic mutation profile of tumor specimen TCGA-B0-5085-01A (aliquot TCGA-B0-5085-01A-01D-1462-08) from TCGA case TCGA-B0-5085, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 76.1 years (27,793 days).
Specimen TCGA-B0-5085-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 498c7b1f-a5a9-4dd8-8edc-50de47c14a44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5085-11A (Solid Tissue Normal), aliquot TCGA-B0-5085-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2283f67-5640-430a-9492-adabbe548e9e

The open-access MAF lists 72 somatic variants for this specimen: 56 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 14, Nonsense Mutation 7, Frame Shift Ins 4, Splice Site 3, Frame Shift Del 2, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AARS2 | c.2255+1G>T p.X752_splice | Splice Site (SNP) | VAF 8/80 reads (10%) | catalogued as COSV55117037; called by muse, varscan2
- AL121899.2 | c.1627A>G p.I543V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1485108022, COSV67352047; called by muse, mutect2, varscan2
- CD180 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 83/289 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs943218625, COSV56517495; called by muse, mutect2, varscan2
- CDCA7 | c.59T>A p.F20Y | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV60721484; called by muse, mutect2, varscan2
- CDK3 | c.238T>A p.F80I | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56914683; called by muse, mutect2, varscan2
- CLEC2D | c.45A>C p.E15D | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV51995443; called by muse, mutect2, varscan2
- CRTC1 | c.1609C>A p.L537I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV58722265; called by muse, mutect2, varscan2
- DDX3X | c.866C>T p.S289L (on ENST00000399959; = p.S290L on NM_001356.5) | Missense Mutation (SNP) | VAF 81/266 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV67864313; called by muse, mutect2, varscan2
- GABRG2 | c.256G>T p.G86* | Nonsense Mutation (SNP) | VAF 29/244 reads (12%) | catalogued as COSV62721421; called by muse, mutect2, varscan2
- GNAI1 | c.28A>T p.K10* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as COSV63524675; called by muse, mutect2, varscan2
- GRAP2 | c.47A>T p.E16V | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59996705; called by muse, mutect2, varscan2
- HUWE1 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as COSV53360242; called by muse, mutect2, varscan2
- IGSF1 | c.1015G>T p.V339L | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as COSV63837256, COSV63839411; called by muse, mutect2, varscan2
- IL6ST | c.668A>G p.N223S | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs199518876, COSV61139731; called by muse, mutect2, varscan2
- JADE3 | c.1966A>C p.K656Q | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV54469290; called by muse, mutect2, varscan2
- JARID2 | c.1155A>T p.K385N | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as COSV59195921; called by muse, mutect2, varscan2
- KIF1B | c.4193C>T p.A1398V (on ENST00000377086 / NM_001365952.1; = p.A1352V on NM_015074.3) | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.306); catalogued as COSV55814094; called by muse, mutect2, varscan2
- LAMB2 | c.460A>T p.T154S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59736759; called by muse, mutect2, varscan2
- LPAR4 | c.765G>T p.M255I | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV70913239; called by muse, mutect2, varscan2
- MAST4 | c.3392C>G p.S1131C (on ENST00000403625 / NM_001164664.2; = p.S942C on NM_015183.3) | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55137964; called by muse, mutect2, varscan2
- MCEE | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as rs779113206, COSV54905813, COSV54906834; called by muse, mutect2, varscan2
- MKRN3 | c.823C>A p.H275N | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV58811622; called by muse, mutect2, varscan2
- MYO15A | c.6430G>A p.A2144T | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.23); catalogued as COSV52763203; called by muse, mutect2, varscan2
- NAP1L2 | c.600C>G p.D200E | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV100999239, COSV65172930; called by muse, mutect2
- OGT | c.2527G>A p.V843I | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.063); catalogued as COSV65481873, COSV65482220; called by muse, mutect2, varscan2
- OR52J3 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 54/306 reads (18%) | catalogued as rs779465901, COSV66746564; called by muse, mutect2, varscan2
- PBRM1 | c.2068A>T p.R690* | Nonsense Mutation (SNP) | VAF 80/168 reads (48%) | catalogued as COSV56288906, COSV56297087; called by muse, mutect2, varscan2
- PCDHB7 | c.1510G>A p.V504I | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.107); catalogued as rs1554280223, COSV50804794; called by muse, mutect2, varscan2
- PHKA1 | c.2381G>T p.W794L | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV59809863; called by muse, mutect2, varscan2
- PRKG1 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV64806207; called by muse, mutect2, varscan2
- PRPF40B | c.2372A>G p.H791R (on ENST00000380281; = p.H778R on NM_012272.3) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.95); catalogued as rs764584707, COSV53306328; called by mutect2, varscan2
- PSTK | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 54/205 reads (26%) | catalogued as rs1017554838, COSV64398895; called by muse, mutect2, varscan2
- PTPRU | c.2312G>T p.R771L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as rs780379580, COSV60530966, COSV60534796; called by muse, mutect2, varscan2
- PXYLP1 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 78/254 reads (31%) | catalogued as COSV53890469, COSV53892543; called by muse, mutect2, varscan2
- RAB7A | c.151A>T p.M51L | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV54043800; called by muse, mutect2, varscan2
- RBM28 | c.946+2T>G p.X316_splice | Splice Site (SNP) | VAF 19/104 reads (18%) | catalogued as COSV56164457; called by muse, mutect2, varscan2
- RPS13 | c.82T>G p.L28V | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV57180502; called by muse, mutect2, varscan2
- SLC6A7 | c.1242G>C p.E414D | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV57940142; called by muse, mutect2, varscan2
- SPRED1 | c.395A>G p.N132S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV54437805, COSV54438398; called by muse, mutect2, varscan2
- STARD6 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs919877753, COSV57143306; called by muse, mutect2, varscan2
- TACC1 | c.629A>C p.E210A | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV52527723; called by muse, mutect2, varscan2
- TCERG1 | c.2382+1G>A p.X794_splice | Splice Site (SNP) | VAF 6/84 reads (7%) | catalogued as COSV57040758; called by muse, mutect2
- TENT4B | c.1381G>A p.G461S (on ENST00000561678 / NM_001365323.2; = p.G446S on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV62548973; called by muse, mutect2, varscan2
- TIPARP | c.1394T>A p.V465D | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55815419; called by muse, mutect2, varscan2
- TTLL1 | c.400A>C p.T134P | Missense Mutation (SNP) | VAF 97/327 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV56740285; called by muse, mutect2, varscan2
- TTN | c.70268C>G p.T23423S (on ENST00000591111; = p.T15999S on NM_003319.4) | Missense Mutation (SNP) | VAF 40/323 reads (12%) | PolyPhen benign (0.347); catalogued as COSV60272538; called by muse, mutect2, varscan2
- VAC14 | c.763A>G p.K255E | Missense Mutation (SNP) | VAF 41/289 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV55756779; called by muse, mutect2, varscan2
- VHL | c.216_217dup p.Q73Pfs*87 | Frame Shift Ins (INS) | VAF 8/20 reads (40%) | catalogued as COSV56563065; called by mutect2, varscan2
- VSIG2 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.839); catalogued as COSV52519255; called by muse, mutect2, varscan2
- WDR19 | c.2478C>A p.D826E | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV56468917; called by muse, mutect2
- ZFHX4 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.098); catalogued as COSV51461556; called by muse, mutect2, varscan2
- MAP3K15 | c.3774dup p.E1259* | Frame Shift Ins (INS) | VAF 70/289 reads (24%) | called by mutect2, pindel, varscan2
- NFATC2 | c.1333del p.L445Sfs*48 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | called by mutect2, pindel
- NMD3 | c.209del p.Q70Rfs*4 | Frame Shift Del (DEL) | VAF 37/159 reads (23%) | called by mutect2, pindel, varscan2
- PNPLA7 | c.2133dup p.G712Wfs*54 | Frame Shift Ins (INS) | VAF 11/30 reads (37%) | called by mutect2, pindel, varscan2
- SLC4A2 | c.2781dup p.P928Sfs*28 | Frame Shift Ins (INS) | VAF 35/126 reads (28%) | called by mutect2, pindel, varscan2
- CLN8 | c.555C>G p.S185= | Silent (SNP) | VAF 23/114 reads (20%) | catalogued as COSV58671322; called by muse, mutect2, varscan2
- DLL3 | c.363T>A p.S121= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as COSV52696279; called by muse, mutect2
- FNDC4 | c.258T>C p.N86= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV53022424; called by muse, mutect2
- GRINA | c.690A>T p.A230= | Silent (SNP) | VAF 39/131 reads (30%) | catalogued as COSV57593360; called by muse, mutect2, varscan2
- HNF4G | c.78A>G p.A26= (on ENST00000354370 / NM_001330561.2; = p.A73= on NM_004133.5) | Silent (SNP) | VAF 57/188 reads (30%) | catalogued as rs1475711386, COSV62972434; called by muse, mutect2, varscan2
- KCNC1 | c.1254T>C p.A418= | Silent (SNP) | VAF 55/146 reads (38%) | catalogued as COSV56397402; called by muse, mutect2, varscan2
- LRIG2 | c.1134T>A p.A378= | Silent (SNP) | VAF 7/138 reads (5%) | catalogued as COSV63163664; called by muse, mutect2
- PITPNM2 | c.1011G>A p.S337= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as rs369669482; called by muse, mutect2, varscan2
- RNF186 | c.276C>G p.P92= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV64296736, COSV64296928; called by muse, mutect2, varscan2
- ROS1 | c.3546A>G p.R1182= | Silent (SNP) | VAF 38/156 reads (24%) | catalogued as rs1228020371, COSV100876053, COSV63860188; called by muse, mutect2, varscan2
- RUFY2 | c.1140T>C p.D380= | Silent (SNP) | VAF 96/276 reads (35%) | catalogued as COSV56260691; called by muse, mutect2, varscan2
- SPHK2 | c.117G>A p.P39= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs776249619, COSV55341025; called by muse, mutect2, varscan2
- THBS2 | c.270C>G p.L90= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV64681478; called by muse, mutect2, varscan2
- TMPRSS9 | c.2499G>A p.Q833= (on ENST00000648592; = p.Q799= on NM_182973.2) | Silent (SNP) | VAF 57/200 reads (29%) | catalogued as COSV53115140; called by muse, mutect2, varscan2
- GUK1 | c.-3+483C>G | Intron (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- LRRC23 | c.*154C>A | 3'UTR (SNP) | VAF 62/206 reads (30%) | catalogued as rs782692868, COSV50394312; called by muse, mutect2, varscan2
